Somatic mutation profile of tumor specimen TARGET-40-0A4HLD-01A (aliquot TARGET-40-0A4HLD-01A-01D) from TARGET case TARGET-40-0A4HLD, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 19.9 years (7,254 days).
Specimen TARGET-40-0A4HLD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3c1bbfc-2c60-4a18-91b7-ae2d12a89294.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4HLD-10A (Blood Derived Normal), aliquot TARGET-40-0A4HLD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d9e1f54-0412-46b8-bbfd-b7ea68cd8190

The open-access MAF lists 67 somatic variants for this specimen: 39 protein-altering or splice-affecting, 18 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 18, RNA 5, Intron 3, 3'UTR 2, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 43/53 reads (81%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGMO | c.1024C>G p.Q342E | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV104417279; called by muse, mutect2, varscan2
- ATP8A1 | c.269T>A p.I90K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100047503; called by muse, mutect2, varscan2
- CHRD | c.1598-4C>A | Splice Region (SNP) | VAF 38/209 reads (18%) | catalogued as rs1222348431; called by muse, mutect2, varscan2
- CR1 | c.2261T>C p.L754P | Missense Mutation (SNP) | VAF 63/343 reads (18%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.991); catalogued as COSV100888080; called by muse, mutect2, varscan2
- FREM1 | c.3714G>A p.M1238I | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV66522721; called by muse, mutect2, varscan2
- IFT80 | c.1274G>T p.S425I | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100424770; called by muse, mutect2, varscan2
- L3MBTL3 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs200526729, COSV62385472; called by muse, mutect2, varscan2
- LRP1B | c.5644A>T p.M1882L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67186660; called by muse, mutect2, varscan2
- MRGPRE | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 82/97 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs751476188, COSV67745749; called by muse, mutect2, varscan2
- NINL | c.3814C>T p.Q1272* | Nonsense Mutation (SNP) | VAF 4/52 reads (8%) | catalogued as rs1471692400; called by muse, mutect2
- SFXN4 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV100045346; called by muse, mutect2
- SIX3 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs1553337714; ClinVar: uncertain significance; called by muse, mutect2
- THSD7B | c.781C>G p.P261A | Missense Mutation (SNP) | VAF 169/309 reads (55%) | SIFT tolerated (0.87); PolyPhen benign (0.009); catalogued as COSV55656988, COSV55729313; called by muse, mutect2, varscan2
- TSPAN8 | c.538C>A p.P180T | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1304841974; called by muse, mutect2, varscan2
- ZNF34 | c.1592A>G p.Y531C | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1375882778; called by muse, mutect2, varscan2
- ZNHIT1 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs771133778; called by muse, mutect2, varscan2
- B3GALT2 | c.388C>A p.H130N | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CACNA1B | c.5440C>T p.Q1814* | Nonsense Mutation (SNP) | VAF 35/179 reads (20%) | called by muse, mutect2, varscan2
- CASP4 | c.280G>C p.A94P | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC112 | c.1258G>A p.G420R | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- COL6A2 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.966); called by muse, mutect2
- CYSLTR2 | c.344C>G p.S115C | Missense Mutation (SNP) | VAF 67/84 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CYSLTR2 | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 53/77 reads (69%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- FLG | c.3393T>A p.H1131Q | Missense Mutation (SNP) | VAF 147/854 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GGT1 | c.710T>C p.I237T | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- HEATR5B | c.1479C>G p.N493K | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.97); PolyPhen benign (0.006); called by muse, varscan2
- IGHV3-35 | c.137T>A p.F46Y | Missense Mutation (SNP) | VAF 84/265 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- KCND2 | c.539C>A p.T180N | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- KDM5A | c.4738A>T p.T1580S | Missense Mutation (SNP) | VAF 66/280 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MPO | c.2145C>A p.N715K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OTUD7B | c.1480A>G p.K494E | Missense Mutation (SNP) | VAF 54/311 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PADI3 | c.797C>G p.S266C | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- PRG2 | c.337A>G p.R113G | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PRPF39 | c.1332G>T p.L444F | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- STAB1 | c.6041T>A p.F2014Y | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- UBIAD1 | c.170G>T p.S57I | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- VSIG8 | c.578G>C p.G193A | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- WRAP73 | c.1363C>G p.Q455E | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ACTL8 | c.201C>A p.I67= | Silent (SNP) | VAF 53/318 reads (17%) | called by muse, mutect2, varscan2
- BMI1 | c.139C>T p.L47= | Silent (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- CHAF1A | c.2034T>C p.F678= | Silent (SNP) | VAF 55/129 reads (43%) | called by muse, mutect2, varscan2
- CYSLTR2 | c.228C>T p.F76= | Silent (SNP) | VAF 45/55 reads (82%) | catalogued as COSV56165115, COSV56166380; called by muse, mutect2, varscan2
- FAM131B | c.933G>A p.K311= | Silent (SNP) | VAF 130/175 reads (74%) | catalogued as rs757950235, COSV58374396; called by muse, mutect2, varscan2
- GCK | c.465G>A p.R155= | Silent (SNP) | VAF 24/148 reads (16%) | catalogued as rs757281286; called by muse, mutect2, varscan2
- H3C13 | c.72A>G p.K24= | Silent (SNP) | VAF 64/171 reads (37%) | catalogued as rs781839414; called by muse, mutect2, varscan2
- HEATR5B | c.1410C>A p.R470= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV99249860; called by muse, varscan2
- KCND2 | c.540C>A p.T180= | Silent (SNP) | VAF 28/130 reads (22%) | called by muse, mutect2, varscan2
- LOXL3 | c.2082C>G p.V694= | Silent (SNP) | VAF 68/194 reads (35%) | called by muse, mutect2, varscan2
- NCOA5 | c.1635T>C p.D545= | Silent (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- NOL4L | c.1272T>C p.S424= | Silent (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- NXPE2 | c.201T>C p.S67= | Silent (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- RNF10 | c.1593C>T p.Y531= | Silent (SNP) | VAF 48/191 reads (25%) | catalogued as rs149497258; called by muse, mutect2, varscan2
- SEMA4A | c.633A>T p.T211= | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as COSV61773830; called by muse, mutect2, varscan2
- SPHKAP | c.4083T>A p.T1361= | Silent (SNP) | VAF 55/120 reads (46%) | called by muse, mutect2, varscan2
- TONSL | c.3778C>T p.L1260= | Silent (SNP) | VAF 49/106 reads (46%) | called by muse, mutect2, varscan2
- ZNF324 | c.420G>A p.S140= | Silent (SNP) | VAF 35/113 reads (31%) | catalogued as rs768268710; called by muse, mutect2, varscan2
- AL353616.1 | n.1593A>G | RNA (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- CCT6B | c.1066-109A>T | Intron (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2, varscan2
- FAM87A | n.2791C>G | RNA (SNP) | VAF 24/90 reads (27%) | catalogued as rs368807142; called by muse, mutect2
- HSPA7 | n.1323T>A | RNA (SNP) | VAF 21/133 reads (16%) | called by muse, mutect2, varscan2
- KNOP1P1 | n.270C>T | RNA (SNP) | VAF 6/59 reads (10%) | catalogued as rs1213457804; called by muse, mutect2
- MED25 | c.2146+134C>T | Intron (SNP) | VAF 3/35 reads (9%) | catalogued as rs1482280643, COSV57205008; called by muse, mutect2
- NMNAT2 | c.*52del | 3'UTR (DEL) | VAF 13/103 reads (13%) | called by mutect2, pindel, varscan2
- OCEL1 | c.*12G>A | 3'UTR (SNP) | VAF 38/91 reads (42%) | catalogued as COSV99285778; called by muse, mutect2, varscan2
- PTGR2 | c.729+22C>A | Intron (SNP) | VAF 27/129 reads (21%) | called by muse, mutect2, varscan2
- UBTFL7 | n.1097A>G | RNA (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
